CPTAC case C3L-02384 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9694fc41-ffe4-4bdc-bb66-38f876c69abe

Demographics
Sex at birth: female; Race: white; Year of birth: 1935; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 81.4 years (29,731 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G3; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 907 days (2.5 years); Progression or recurrence: no; Days to last follow up: 907 days (2.5 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.1 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 15; Margin status: Uninvolved.

Follow-up (4 entries)
- Days to follow up: 372 days (1.0 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 725 days (2.0 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 907 days (2.5 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 907 days (2.5 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.

Other clinical attributes
- Weight: 57.61 kg; Height: 162.56 cm; BMI: 21.8.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (9 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02384-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 46 days; Initial weight: 240 mg; Time between excision and freezing: 18 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02384-21: Section location: Tumor involves 25% of anterior and posterior endometrium; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-02384-02: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 60 mg.
- Sample C3L-02384-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 46 days; Time between excision and freezing: 18 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Samples C3L-02384-31, C3L-02384-32, C3L-02384-71, C3L-02384-72, C3L-02384-73 (5 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Sample C3L-02384-74: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 46 days; Method of sample procurement: Blood Draw.
